Somatic mutation profile of tumor specimen TCGA-FJ-A871-01A (aliquot TCGA-FJ-A871-01A-11D-A34U-08) from TCGA case TCGA-FJ-A871, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 49.4 years (18,051 days).
Specimen TCGA-FJ-A871-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d54673f8-4c15-481f-be73-d6bd3847dc69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FJ-A871-10A (Blood Derived Normal), aliquot TCGA-FJ-A871-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72fc9f70-9a4f-45d7-a139-8616a6b3bc18

The open-access MAF lists 56 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 35, Silent 12, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 50/70 reads (71%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PEX13 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 90/235 reads (38%) | catalogued as rs553968959, COSV54369896, COSV99692656; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 48/136 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs121909238, CM051214, COSV100910602, COSV64296545, COSV64296755; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1027-1G>A p.X343_splice | Splice Site (SNP) | VAF 19/49 reads (39%) | hotspot (GDC flag); catalogued as rs1057517809, CS1413088, COSV64290834, COSV64293694, COSV64298429; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGBL1 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); catalogued as rs767859259, COSV69808419; called by muse, mutect2, varscan2
- ASB4 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV57947295; called by muse, mutect2, varscan2
- CNTLN | c.1949T>C p.I650T | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV52089920; called by muse, mutect2, varscan2
- CNTN3 | c.2347A>C p.N783H | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV55179972; called by muse, mutect2, varscan2
- COL4A5 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.812); catalogued as COSV60367628; called by muse, mutect2
- COLEC12 | c.1953+1G>A p.X651_splice | Splice Site (SNP) | VAF 38/120 reads (32%) | catalogued as COSV68372600; called by muse, mutect2, varscan2
- CREBBP | c.5333C>A p.S1778* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as COSV52115130, COSV99268481; called by muse, mutect2, varscan2
- CTNND2 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV58911333; called by muse, mutect2, varscan2
- CUBN | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs575021189, COSV64707019; called by muse, mutect2, varscan2
- DAPK1 | c.3113G>A p.R1038H | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs768648374, COSV63785545; called by muse, mutect2, varscan2
- DIPK2B | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 51/62 reads (82%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs182977348, COSV67641539; called by muse, mutect2, varscan2
- ERG28 | c.225G>C p.T75= | Splice Region (SNP) | VAF 22/62 reads (35%) | catalogued as COSV53163809; called by muse, mutect2, varscan2
- GPATCH8 | c.2744A>G p.D915G | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV59196739; called by muse, mutect2, varscan2
- KMT2C | c.1826A>G p.H609R | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV51478205; called by muse, mutect2, varscan2
- LAMA5 | c.7912G>A p.E2638K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV53367317; called by muse, mutect2, varscan2
- MYO15A | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV52762023; called by muse, mutect2, varscan2
- OLFM3 | c.898G>A p.G300S (on ENST00000338858 / NM_001288821.1; = p.G280S on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58801805; called by muse, mutect2, varscan2
- OR10C1 | c.667C>T p.L223F (on ENST00000622521; = p.L221F on NM_013941.3) | Missense Mutation (SNP) | VAF 95/249 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV65823665; called by muse, mutect2, varscan2
- OR8J1 | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57319444; called by muse, mutect2, varscan2
- PCDHGA5 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.177); catalogued as rs1264187226, COSV54000286; called by muse, mutect2, varscan2
- PTBP3 | c.1399T>C p.F467L | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.367); catalogued as COSV57585605; called by muse, mutect2, varscan2
- RTN1 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.366); catalogued as rs1196838903, COSV99954549; called by muse, mutect2, varscan2
- RYR2 | c.6985G>A p.E2329K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63703069; called by muse, mutect2, varscan2
- SEC23A | c.2213C>G p.S738C | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV56977009; called by muse, mutect2, varscan2
- SF3B1 | c.554A>G p.N185S | Missense Mutation (SNP) | VAF 115/298 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV59212351; called by muse, mutect2, varscan2
- SIK3 | c.2951A>G p.Y984C (on ENST00000445177 / NM_001366686.2; = p.Y942C on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.944); catalogued as COSV52620348; called by muse, mutect2, varscan2
- SLC29A1 | c.308A>G p.H103R | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as rs1350769851, COSV57578059, COSV57579734; called by muse, mutect2, varscan2
- SLC44A4 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.299); catalogued as COSV57668547; called by muse, mutect2, varscan2
- SPHKAP | c.4796C>T p.T1599M (on ENST00000392056 / NM_001142644.2; = p.T1570M on NM_030623.3) | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs142164970; called by muse, mutect2, varscan2
- TAF1L | c.4750C>T p.R1584W | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs147667610; called by muse, mutect2, varscan2
- TMEM74 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs565869013, COSV52463348; called by muse, mutect2, varscan2
- TMPRSS15 | c.1931A>G p.K644R | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV53045252; called by muse, mutect2, varscan2
- TSC22D1 | c.312A>C p.Q104H | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71776097; called by muse, mutect2, varscan2
- URM1 | c.227G>A p.W76* | Nonsense Mutation (SNP) | VAF 31/79 reads (39%) | catalogued as COSV100864848; called by muse, mutect2, varscan2
- ZADH2 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV59269317, COSV59269480; called by muse, mutect2, varscan2
- ZP2 | c.1882C>G p.P628A | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as rs761862700, COSV54815660, COSV99076910; called by muse, mutect2, varscan2
- ARID1A | c.6749_6750del p.E2250Vfs*27 | Frame Shift Del (DEL) | VAF 88/160 reads (55%) | called by pindel, varscan2
- MST1 | c.1603del p.R535Gfs*37 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel
- USP3 | c.1138_1143del p.T380_E381del | In Frame Del (DEL) | VAF 30/102 reads (29%) | called by mutect2, pindel, varscan2
- COL11A2 | c.2061C>T p.D687= (on ENST00000341947 / NM_080680.3; = p.D580= on NM_080679.2) | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs764335860, COSV59497360; called by muse, mutect2, varscan2
- CXCR1 | c.957C>T p.I319= | Silent (SNP) | VAF 56/122 reads (46%) | catalogued as COSV55282546; called by muse, mutect2, varscan2
- ERICH3 | c.2980T>C p.L994= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV58613811; called by muse, mutect2, varscan2
- LTBP2 | c.3219C>T p.F1073= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as rs142012825; called by muse, mutect2, varscan2
- MFAP3L | c.366A>G p.K122= | Silent (SNP) | VAF 89/202 reads (44%) | catalogued as COSV64372712; called by muse, mutect2, varscan2
- MYH2 | c.2280C>T p.T760= | Silent (SNP) | VAF 74/224 reads (33%) | catalogued as COSV55444502; called by muse, mutect2, varscan2
- PCDHB1 | c.468C>T p.S156= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV60631585; called by muse, mutect2, varscan2
- PCDHB3 | c.1797C>T p.N599= | Silent (SNP) | VAF 62/175 reads (35%) | catalogued as COSV99164147; called by muse, mutect2, varscan2
- PLD3 | c.183A>G p.E61= | Silent (SNP) | VAF 53/137 reads (39%) | catalogued as COSV62925490; called by muse, mutect2, varscan2
- SELENOK | c.102G>T p.V34= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as rs1160696949, COSV72177902; called by muse, mutect2, varscan2
- THOC6 | c.870G>A p.K290= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV50187939, COSV50188020; called by muse, mutect2, varscan2
- WWC2 | c.138G>A p.T46= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs748213423, COSV100968136; called by muse, varscan2
